Somatic mutation profile of tumor specimen MMRF_1784_1_BM_CD138pos (aliquot MMRF_1784_1_BM_CD138pos_T1_KBS5U_L06442) from MMRF case MMRF_1784, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.5 years (22,099 days).
Specimen MMRF_1784_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4547148f-cb3d-4b08-a1d3-677ac7f6601f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1784_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1784_1_PB_Whole_C2_KBS5U_L06497; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2b22bd7-45b7-4241-ba6b-e95e98635257

The open-access MAF lists 130 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 31, Silent 19, Intron 6, 5'UTR 4, Nonsense Mutation 4, RNA 3, 3'Flank 3, 5'Flank 3, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.6431A>G p.N2144S | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs137854461, CM930247; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGF23 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs193922702, CM002777, COSV52975411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs1463721436; called by muse, mutect2
- ANAPC2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.037); catalogued as rs746894266; called by muse, mutect2, varscan2
- CADPS2 | c.3842G>A p.G1281E | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745398682; called by muse, mutect2, varscan2
- COPE | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139916543; called by muse, mutect2, varscan2
- CPS1 | c.3904C>G p.P1302A | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV51803179; called by muse, mutect2, varscan2
- FAM110B | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs138142337; called by muse, mutect2, varscan2
- FBN1 | c.4137C>G p.D1379E | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.702); catalogued as rs760803105; called by muse, mutect2, varscan2
- GK2 | c.450T>G p.S150R | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750628717; called by muse, mutect2, varscan2
- HAUS5 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs758476156; called by muse, mutect2, varscan2
- IGKJ4 | c.4A>C p.T2P | Missense Mutation (SNP) | VAF 18/65 reads (28%) | PolyPhen possibly damaging (0.652); catalogued as rs761601499; called by muse, varscan2
- IGKV4-1 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs375238504; called by muse, varscan2
- IGLV3-1 | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs373323725; called by muse, mutect2, varscan2
- IGLV3-1 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs376783127; called by muse, mutect2, varscan2
- NOP58 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1383718336; called by muse, mutect2, varscan2
- NYAP2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1039068937, COSV56006471, COSV99797136; called by muse, mutect2, varscan2
- PABPC5 | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1409518697; called by muse, mutect2
- PLA2G7 | c.161C>G p.T54S | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1403043435; called by muse, varscan2
- PPP1R15B | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1438899237, COSV65816201; called by muse, mutect2, varscan2
- RAET1G | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 143/171 reads (84%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV66275346; called by muse, mutect2, varscan2
- SMC5 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs748788617; called by muse, mutect2, varscan2
- SPTBN5 | c.6341C>T p.T2114M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs965572288; called by muse, mutect2, varscan2
- AKNA | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ATRNL1 | c.1277T>C p.V426A | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CILK1 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CNNM2 | c.2211G>C p.E737D | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CRNN | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- DISP3 | c.276G>T p.M92I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DNLZ | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- EIF2AK1 | c.578dup p.Y193* | Nonsense Mutation (INS) | VAF 29/175 reads (17%) | called by mutect2, pindel, varscan2
- FOXA1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GFY | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- GRID1 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- IGHG1 | c.341-1G>A p.X114_splice | Splice Site (SNP) | VAF 31/35 reads (89%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.177); called by muse, varscan2
- IGHV1-69D | c.153T>A p.Y51* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | called by muse, varscan2
- IGHV1-69D | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by mutect2, varscan2
- IGHV2-70D | c.100A>C p.T34P | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KMT2B | c.8046del p.G2683Vfs*55 | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- KMT2C | c.9533A>G p.K3178R | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- MAPK13 | c.418-1G>A p.X140_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- MYO18B | c.2080del p.R694Efs*27 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- MYRF | c.89C>A p.T30N (on ENST00000278836 / NM_001127392.3; = p.T21N on NM_013279.4) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRP1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NUP98 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 66/158 reads (42%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PDIK1L | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PINLYP | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- RAB24 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 138/271 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RCOR3 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 21/261 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2
- SKA3 | c.759T>A p.D253E | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPTA1 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THNSL1 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TMC1 | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TMEM140 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- TMEM255B | c.77T>A p.L26H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBXN7 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2
- WDR3 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF710 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2
- ZNF74 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 129/235 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.9810C>T p.F3270= | Silent (SNP) | VAF 102/215 reads (47%) | catalogued as rs138010392; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAP1 | c.1974C>T p.N658= (on ENST00000393609 / NM_001040118.2; = p.N413= on NM_015242.4) | Silent (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- CACNB1 | c.1356C>T p.D452= | Silent (SNP) | VAF 69/121 reads (57%) | called by muse, mutect2, varscan2
- DYRK3 | c.843G>A p.R281= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as rs1436877311; called by muse, mutect2, varscan2
- ELFN1 | c.1788G>A p.P596= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1280240725; called by muse, mutect2, varscan2
- GOLGB1 | c.483C>T p.S161= | Silent (SNP) | VAF 66/213 reads (31%) | catalogued as rs951972412; called by muse, mutect2, varscan2
- HJV | c.147C>G p.S49= | Silent (SNP) | VAF 26/273 reads (10%) | called by muse, mutect2, varscan2
- IGSF22 | c.1737C>T p.H579= | Silent (SNP) | VAF 68/202 reads (34%) | catalogued as rs878937493; called by muse, mutect2, varscan2
- LRIT2 | c.1383G>A p.E461= | Silent (SNP) | VAF 50/86 reads (58%) | catalogued as rs752102061; called by muse, mutect2, varscan2
- MPP6 | c.576A>G p.E192= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- OPHN1 | c.1158C>T p.G386= | Silent (SNP) | VAF 91/118 reads (77%) | called by muse, mutect2, varscan2
- PCDH15 | c.2826T>C p.G942= | Silent (SNP) | VAF 82/238 reads (34%) | catalogued as COSV57273024; called by muse, mutect2, varscan2
- PITPNM1 | c.2658G>A p.L886= | Silent (SNP) | VAF 135/324 reads (42%) | catalogued as rs1292835027; called by muse, mutect2, varscan2
- PSMD5 | c.573G>A p.E191= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs1245610542; called by muse, mutect2, varscan2
- SEMA6B | c.1245G>A p.A415= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs144907430, COSV100015113; called by muse, mutect2, varscan2
- SLC5A4 | c.726C>T p.S242= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs749573452, COSV56668307; called by muse, mutect2, varscan2
- TAF5L | c.1449G>A p.L483= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- TLN1 | c.5595A>G p.A1865= | Silent (SNP) | VAF 60/197 reads (30%) | called by muse, mutect2, varscan2
- VTN | c.1041C>T p.D347= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs781904743; called by muse, mutect2, varscan2
- ABCC13 | n.3396A>C | RNA (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- ACE | c.1922-273C>T | Intron (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2
- ADGRL2 | c.*854A>G | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- AFF4 | c.*3526_*3529del | 3'UTR (DEL) | VAF 27/97 reads (28%) | catalogued as rs915780229; called by mutect2, pindel, varscan2
- AP001267.5 | c.-799+29420C>T | Intron (SNP) | VAF 134/355 reads (38%) | called by muse, mutect2, varscan2
- AP001993.1 | chr11:127099901 C>G | 3'Flank (SNP) | VAF 19/432 reads (4%) | called by muse, mutect2
- ATE1 | c.*3005A>T | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.604A>G | RNA (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- CDHR2 | chr5:176595810 A>C | 3'Flank (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- CPAMD8 | c.645+41C>T | Intron (SNP) | VAF 25/94 reads (27%) | catalogued as rs566800785; called by muse, mutect2
- CTTNBP2NL | c.*3299A>T | 3'UTR (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- CYP4Z2P | n.409C>T | RNA (SNP) | VAF 29/66 reads (44%) | catalogued as rs1010950632; called by muse, mutect2, varscan2
- DCAF4L2 | c.*839_*840insACAAAAAA | 3'UTR (INS) | VAF 32/86 reads (37%) | called by mutect2, varscan2
- DDI1 | c.*170dup | 3'UTR (INS) | VAF 35/162 reads (22%) | called by mutect2, pindel, varscan2
- FCRL5 | c.-118C>T | 5'UTR (SNP) | VAF 33/267 reads (12%) | called by muse, mutect2, varscan2
- FIGN | c.-26T>C | 5'UTR (SNP) | VAF 69/203 reads (34%) | called by muse, mutect2, varscan2
- FSTL5 | c.*1474A>C | 3'UTR (SNP) | VAF 45/100 reads (45%) | catalogued as rs1337359295; called by muse, mutect2, varscan2
- GPR107 | c.*3244A>T | 3'UTR (SNP) | VAF 66/244 reads (27%) | called by muse, mutect2, varscan2
- HEMK1 | c.*3706C>T | 3'UTR (SNP) | VAF 8/180 reads (4%) | catalogued as rs925981244; called by muse, mutect2
- ICA1L | c.*1455G>A | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- IGHD5-5 | chr14:105916825 ins GCCGCC | 5'Flank (INS) | VAF 11/17 reads (65%) | called by mutect2, varscan2
- IGKV4-1 | c.-3A>G | 5'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2
- IKZF3 | c.*1363A>G | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- LPP | c.*14481G>A | 3'UTR (SNP) | VAF 14/109 reads (13%) | called by muse, varscan2
- MID1 | c.*1173T>C | 3'UTR (SNP) | VAF 24/28 reads (86%) | called by muse, mutect2, varscan2
- MLLT6 | c.*1598A>G | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- MMUT | c.*1248C>A | 3'UTR (SNP) | VAF 63/120 reads (53%) | called by muse, mutect2, varscan2
- MORC2 | c.1074-127A>C | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- MUC15 | c.*204G>A | 3'UTR (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- NDRG1 | c.*1211G>A | 3'UTR (SNP) | VAF 80/149 reads (54%) | called by muse, mutect2, varscan2
- OR52K1 | chr11:4489959 A>C | 3'Flank (SNP) | VAF 103/268 reads (38%) | called by muse, mutect2, varscan2
- PDE4D | c.*2825A>G | 3'UTR (SNP) | VAF 50/76 reads (66%) | called by muse, mutect2, varscan2
- PITPNM2 | c.*637C>G | 3'UTR (SNP) | VAF 38/108 reads (35%) | called by muse, mutect2, varscan2
- PTPRD | c.*2677C>A | 3'UTR (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- RRP36 | c.*319C>T | 3'UTR (SNP) | VAF 57/98 reads (58%) | called by muse, mutect2, varscan2
- SEC22C | c.*4046A>G | 3'UTR (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- SGCZ | c.*273T>C | 3'UTR (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- SLC1A2 | c.*186C>T | 3'UTR (SNP) | VAF 32/110 reads (29%) | catalogued as rs1342864586; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*2680A>T | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- STC2 | c.*313G>A | 3'UTR (SNP) | VAF 75/232 reads (32%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*749T>C | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- TECRL | c.*2113T>A | 3'UTR (SNP) | VAF 33/68 reads (49%) | catalogued as rs568197231; called by muse, mutect2, varscan2
- TENM3 | c.*1592G>A | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- TMEM51 | c.-51T>A | 5'UTR (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- TNS4 | c.*1714C>T | 3'UTR (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.894+167G>A | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as rs754539723; called by muse, mutect2, varscan2
- USP40 | c.2914+629G>T | Intron (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- VCP | c.*939C>A | 3'UTR (SNP) | VAF 59/217 reads (27%) | called by muse, mutect2, varscan2
- WDR74 | chr11:62839857 T>C | 5'Flank (SNP) | VAF 82/303 reads (27%) | called by muse, mutect2, varscan2
- ZNF552 | chr19:57819809 G>A | 5'Flank (SNP) | VAF 71/251 reads (28%) | called by muse, mutect2, varscan2
